Somatic mutation profile of tumor specimen 0DLX56 from CCDI case PBBZME, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.9 years (3,259 days).
Specimen 0DLX56: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c811246f-bc67-4e69-aca5-ddffe92d7f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80e6ea9d-3959-4611-93f7-a6c6e90d6378

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, Frame Shift Ins 2, Intron 1, 5'UTR 1, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 426/1032 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 50/1982 reads (3%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60786475, COSV60810612; called by muse, mutect2
- FAM217B | c.627dup p.T210Hfs*16 | Frame Shift Ins (INS) | VAF 350/1007 reads (35%) | catalogued as rs764018014; called by mutect2, pindel, varscan2
- MATR3 | c.1779-1G>A p.X593_splice | Splice Site (SNP) | VAF 315/678 reads (46%) | catalogued as COSV100735343, COSV63080772; called by muse, mutect2, varscan2
- OTUD6A | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 281/644 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs757064205, COSV100611099; called by muse, mutect2, varscan2
- AHCTF1 | c.4340G>T p.C1447F (on ENST00000366508; = p.C1421F on NM_015446.5) | Missense Mutation (SNP) | VAF 400/999 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DNAJB4 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 505/1088 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR50 | c.621C>G p.C207W | Missense Mutation (SNP) | VAF 605/1350 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MGA | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 214/497 reads (43%) | called by muse, mutect2, varscan2
- MMP15 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 204/429 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPN18 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 360/808 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SQLE | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 27/900 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.269); called by muse, mutect2
- ZNF292 | c.7613dup p.N2538Kfs*6 | Frame Shift Ins (INS) | VAF 558/696 reads (80%) | called by mutect2, varscan2
- CNBD2 | c.534G>A p.P178= | Silent (SNP) | VAF 446/1148 reads (39%) | catalogued as rs368014098; called by muse, mutect2, varscan2
- GRIA2 | c.324C>T p.H108= | Silent (SNP) | VAF 601/1273 reads (47%) | catalogued as rs753466564, COSV99645290; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR8H3 | c.132G>T p.V44= | Silent (SNP) | VAF 71/1568 reads (5%) | called by muse, mutect2
- RP2 | c.45G>A p.S15= | Silent (SNP) | VAF 408/832 reads (49%) | called by muse, mutect2, varscan2
- SPACA3 | c.312G>T p.L104= | Silent (SNP) | VAF 314/686 reads (46%) | called by muse, mutect2, varscan2
- TEX55 | c.891C>T p.L297= | Silent (SNP) | VAF 494/961 reads (51%) | catalogued as rs1305607263, COSV99817522; called by muse, mutect2, varscan2
- ZDHHC1 | c.381C>T p.H127= | Silent (SNP) | VAF 567/1271 reads (45%) | catalogued as rs375124774; called by muse, mutect2, varscan2
- ABI2 | c.1193-5620C>T | Intron (SNP) | VAF 346/610 reads (57%) | called by muse, mutect2, varscan2
- BTLA | c.-77C>T | 5'UTR (SNP) | VAF 20/239 reads (8%) | catalogued as rs1434355304; called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 22/528 reads (4%) | called by muse, mutect2
